Gene-level copy-number profile of tumor specimen HTMCP-02-15-01099-01A from CGCI case HTMCP-02-15-01099, project CGCI-HTMCP-LC (HIV+ Tumor Molecular Characterization Project - Lung Cancer). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenosquamous carcinoma; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage II; Age at diagnosis: 59.6 years (21,753 days).
Specimen HTMCP-02-15-01099-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 0db072da-b5d3-490e-8231-770dc9357b6f.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-02-15-01099-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,719 have no estimate.
https://portal.gdc.cancer.gov/files/17020765-7187-447b-b73f-3983c743aa24

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 572; copy number 1: 13,548; copy number 2: 37,110; copy number 3: 7,383; copy number 4: 149; copy number 5: 84; copy number 7: 17; copy number 8: 4; copy number 9: 21; copy number 10: 4; copy number 11: 8; copy number 13: 2; copy number 80: 2.

Homozygous deletions (total copy number 0; autosomes only): 60 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:2,013,213–2,185,395, 6 genes (within-gene range 0–3): AL391845.2, GABRD, AL391845.1, PRKCZ, AL590822.2, PRKCZ-AS1.
- chr5:6,371,874–6,378,571, 1 gene: MED10.
- chr5:176,542,511–176,595,974, 3 genes (within-gene range 0–3): CDHR2, RN7SL684P, Y_RNA.
- chr9:12,134–118,204, 10 genes: DDX11L5, WASHC1, MIR1302-9HG, MIR1302-9, FAM138C, AL449043.2, PGM5P3-AS1, AL449043.1, LINC01388, FOXD4.
- chr15:21,328,380–21,946,641, 35 genes: AC060814.4, AC060814.3, LONRF2P4, AC060814.2, CXADRP2, AC060814.1, GRAMD4P6, POTEB3, MIR3118-3, U6, NF1P9, MIR5701-2, AC183088.4, AC183088.2, AC183088.1, LINC02203, AC183088.3, AC135068.6, AC135068.2, AC135068.12, AC135068.11, AC135068.1, AC135068.4, AC135068.5, AC135068.8, AC135068.7, AC135068.9, AC135068.10, AC135068.3, AC134981.1, MIR3118-4, POTEB, RNU6-631P, ZNF519P3, NF1P2.
- chr15:22,145,939–22,160,868, 3 genes: AC010760.1, RPS8P10, IGHV1OR15-1.
- chr17:352,638–357,581, 2 genes (within-gene range 0–1): AC129507.2, AC129507.3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 142 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:177,212,563–177,392,697, 13 genes, copy number 5 (within-gene range 2–5): HNRNPA3, MIR4444-1, NFE2L2, DNAJC19P5, MIR3128, AC079305.1, AC019080.1, AC019080.3, AC019080.4, MIR6512, AC019080.5, H3P7, AC019080.2.
- chr3:4,979,437–4,985,323, 1 gene, copy number 9 (within-gene range 1–9): BHLHE40.
- chr7:63,011,463–63,011,569, 1 gene, copy number 5: RNU6-417P.
- chr9:40,883,634–40,929,092, 2 genes, copy number 8: AL353626.2, MIR1299.
- chr9:64,878,790–64,889,063, 1 gene, copy number 5 (within-gene range 2–5): AC125634.1.
- chr9:97,904,489–97,944,856, 4 genes, copy number 5: TRMO, Y_RNA, AL499604.1, HEMGN.
- chr11:48,526,064–48,908,946, 9 genes, copy number 7: OR4A43P, OR4A45P, OR4A41P, OR4A42P, OR4A44P, AC027369.6, AC027369.3, AC027369.4, AC027369.5.
- chr11:54,591,480–54,725,816, 11 genes, copy number 5: OR4C50P, OR4C46, OR4C7P, OR4R2P, OR4A4P, OR4A3P, OR4A2P, OR4A8, OR4A7P, OR4A5, OR4A6P.
- chr11:62,559,596–62,771,606, 27 genes, copy number 5: EEF1G, AP002990.1, MIR6747, TUT1, MTA2, EML3, AP001458.1, ROM1, B3GAT3, GANAB, INTS5, AP001458.2, C11orf98, LBHD1, CSKMT, SNORA57, UQCC3, UBXN1, LRRN4CL, BSCL2, HNRNPUL2-BSCL2, GNG3, HNRNPUL2, TTC9C, ZBTB3, POLR2G, AP001160.2.
- chr11:65,455,258–65,574,198, 12 genes, copy number 7–13: AP000769.1, LINC02736, AP000769.6, AP000769.2, AP000769.5, SNRPGP19, SCYL1, LTBP3, AP001362.1, ZNRD2-AS1, ZNRD2, FAM89B.
- chr11:101,890,674–102,625,332, 20 genes, copy number 9 (within-gene range 3–9): ANGPTL5, CEP126, CFAP300, RNA5SP535, AP001527.1, AP001527.2, YAP1, AP000942.2, AP000942.1, AP000942.3, AP000942.4, RNU6-952P, AP000942.5, BIRC3, BIRC2, TMEM123, AP001830.1, AP001830.2, MMP7, MMP20.
- chr14:18,333,726–18,419,273, 3 genes, copy number 5–13: CR383658.1, CR383658.2, BNIP3P6.
- chr15:21,951,242–22,095,857, 10 genes, copy number 11–80 (within-gene range 1–80): MIR5701-3, OR11J6P, AC134980.1, OR11H3P, AC134980.2, OR11K1P, OR4Q1P, OR4H6P, OR4M2, OR4N4.
- chr15:22,178,107–22,185,402, 2 genes, copy number 8: IGHV1OR15-3, IGHV4OR15-8.
- chr21:7,744,962–8,454,792, 26 genes, copy number 5: SMIM11B, FAM243B, SMIM34B, KCNE1B, CU633980.1, FP671120.5, FP671120.4, MIR6724-1, FP671120.1, MIR3648-1, FP671120.2, FP671120.6, RNA5-8SN2, MIR6724-2, FP671120.3, FP671120.7, 5_8S_rRNA, FP236383.3, MIR6724-3, FP236383.1, FP236383.4, RNA5-8SN3, MIR6724-4, FP236383.2, FP236383.5, RNA5-8SN1.

Autosomal genes at a single copy (total copy number 1): 11,637. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
